Somatic mutation profile of tumor specimen TCGA-A3-A6NI-01A (aliquot TCGA-A3-A6NI-01A-11D-A33K-10) from TCGA case TCGA-A3-A6NI, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 47.1 years (17,190 days).
Specimen TCGA-A3-A6NI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56f45a33-77cf-4148-9ab3-57136ba9ae98.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-A6NI-10A (Blood Derived Normal), aliquot TCGA-A3-A6NI-10A-01D-A33K-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5110997d-3c77-4fd5-acc5-70c8ed34b6d0

The open-access MAF lists 85 somatic variants for this specimen: 62 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 21, Frame Shift Del 8, Splice Site 4, Frame Shift Ins 4, Intron 2, Nonsense Mutation 2, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.2729C>T p.T910M | Missense Mutation (SNP) | VAF 23/89 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1238758086, COSV60785486, COSV60802491; ClinVar: other / uncertain significance; called by muse, mutect2, varscan2
- VHL | c.341-2A>C p.X114_splice | Splice Site (SNP) | VAF 21/49 reads (43%) | hotspot (GDC flag); catalogued as CS071275, COSV56542830, COSV56544966, COSV56548666, COSV56554645; called by muse, mutect2, varscan2
- ADCY1 | c.421G>T p.A141S | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.97); PolyPhen benign (0.006); catalogued as rs779862034, COSV99811418; called by muse, mutect2, varscan2
- AGO4 | c.1558G>T p.V520L | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as COSV100942793; called by muse, mutect2, varscan2
- AP3D1 | c.2336A>G p.E779G | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.018); catalogued as COSV100642427; called by muse, mutect2, varscan2
- CCDC126 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV100277858; called by muse, mutect2, varscan2
- CCDC126 | c.314A>T p.D105V | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as COSV100277862; called by muse, mutect2, varscan2
- CEP290 | c.4415C>A p.A1472E | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs557052114, COSV100467983; called by muse, mutect2, varscan2
- CNDP1 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100722210; called by muse, mutect2, varscan2
- COL11A1 | c.598A>G p.T200A | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV62196533; called by muse, mutect2, varscan2
- COL28A1 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV101258356; called by muse, mutect2, varscan2
- CREBBP | c.4054C>A p.P1352T | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV99268847; called by muse, mutect2, varscan2
- CRIP3 | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs753487236, COSV99240171; called by muse, mutect2, varscan2
- CSPP1 | c.1454C>G p.P485R (on ENST00000676605; = p.P444R on NM_024790.6) | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99138079; called by muse, mutect2, varscan2
- DDX42 | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63789738; called by muse, mutect2, varscan2
- DENND2C | c.1742T>A p.V581E (on ENST00000393274 / NM_001256404.2; = p.V524E on NM_198459.4) | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV101283895; called by muse, mutect2
- DGKQ | c.2039A>G p.N680S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs910667967, COSV99297569; called by muse, mutect2, varscan2
- DNAH11 | c.11183T>G p.L3728R | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV100177681; called by muse, mutect2, varscan2
- DNAJC10 | c.671G>C p.S224T | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as COSV99898949; called by muse, mutect2, varscan2
- DZIP3 | c.3268C>T p.Q1090* | Nonsense Mutation (SNP) | VAF 20/77 reads (26%) | catalogued as COSV100847669; called by muse, mutect2, varscan2
- EPB41L3 | c.2044C>T p.P682S | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.046); catalogued as rs893718321, COSV100548270, COSV59471949; called by muse, mutect2, varscan2
- FGFR4 | c.1523A>G p.N508S | Missense Mutation (SNP) | VAF 85/187 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as COSV99449010; called by muse, mutect2, varscan2
- GRIN2A | c.3446A>G p.D1149G | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV100408610; called by muse, mutect2, varscan2
- GZMM | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs1267600810, COSV99198810; called by muse, mutect2
- HAP1 | c.1350G>A p.M450I | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100169446; called by muse, mutect2, varscan2
- HIVEP1 | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.69); catalogued as rs267600784, COSV101044812, COSV65099429; called by muse, mutect2, varscan2
- HPSE2 | c.581C>A p.S194Y | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); catalogued as COSV100985169; called by muse, mutect2, varscan2
- LAS1L | c.1034A>C p.E345A | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV100408487; called by muse, mutect2, varscan2
- MDC1 | c.523C>G p.L175V | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.525); catalogued as COSV100902652; called by muse, mutect2, varscan2
- MKRN1 | c.986+2T>C p.X329_splice | Splice Site (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99751462; called by muse, mutect2, varscan2
- NSMF | c.1186A>C p.N396H (on ENST00000371475 / NM_001130969.3; = p.N394H on NM_015537.4) | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99689069; called by muse, mutect2, varscan2
- OR13F1 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100594695; called by muse, mutect2, varscan2
- OR5AS1 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV57982402; called by muse, mutect2, varscan2
- PRDM15 | c.2258+1G>T p.X753_splice | Splice Site (SNP) | VAF 25/95 reads (26%) | catalogued as COSV99519464; called by muse, mutect2, varscan2
- ROS1 | c.5715G>T p.E1905D | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100876586; called by muse, mutect2, varscan2
- RPLP0 | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.076); catalogued as COSV99935266; called by muse, mutect2, varscan2
- SLC30A9 | c.1105A>G p.R369G | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV100047998; called by muse, mutect2, varscan2
- SMARCA2 | c.1939G>T p.E647* | Nonsense Mutation (SNP) | VAF 44/207 reads (21%) | catalogued as COSV100570451; called by muse, mutect2, varscan2
- STAR | c.394A>T p.R132W | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.659); catalogued as COSV99378924; called by muse, mutect2, varscan2
- STAT6 | c.2022G>C p.M674I | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.098); catalogued as COSV100272564; called by muse, mutect2, varscan2
- SULT1C4 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99731489; called by muse, mutect2, varscan2
- TESMIN | c.178A>C p.K60Q | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.01); catalogued as COSV99663419; called by muse, mutect2, varscan2
- TIAM1 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV54538084; called by muse, mutect2, varscan2
- WAPL | c.2274G>C p.K758N | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.398); catalogued as COSV99556323; called by muse, mutect2, varscan2
- ZNF562 | c.865G>C p.E289Q (on ENST00000453372 / NM_001130032.2; = p.E217Q on NM_017656.4) | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV99530562; called by muse, mutect2, varscan2
- ADCY10 | c.340_341del p.N114Hfs*7 | Frame Shift Del (DEL) | VAF 14/76 reads (18%) | called by mutect2, pindel, varscan2
- ASAH2 | c.519C>G p.N173K | Missense Mutation (SNP) | VAF 76/267 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP13A3 | c.2257_2260dup p.T754Ifs*18 | Frame Shift Ins (INS) | VAF 18/56 reads (32%) | called by mutect2, pindel, varscan2
- BRD8 | c.2671del p.D891Tfs*22 | Frame Shift Del (DEL) | VAF 27/127 reads (21%) | called by mutect2, pindel, varscan2
- DDX60L | c.352del p.D118Mfs*26 | Frame Shift Del (DEL) | VAF 25/99 reads (25%) | called by mutect2, pindel, varscan2
- FAR2 | c.858_860delinsT p.A287Cfs*11 | Frame Shift Del (DEL) | VAF 21/75 reads (28%) | called by pindel, varscan2*
- MFSD12 | c.1038dup p.G347Rfs*67 | Frame Shift Ins (INS) | VAF 30/116 reads (26%) | called by mutect2, pindel, varscan2
- REPS2 | c.1661dup p.D555Gfs*14 | Frame Shift Ins (INS) | VAF 91/179 reads (51%) | called by mutect2, pindel, varscan2
- RUNDC3B | c.155dup p.C52Wfs*3 | Frame Shift Ins (INS) | VAF 23/75 reads (31%) | called by mutect2, pindel, varscan2
- SI | c.1128_1146+3del p.X376_splice | Splice Site (DEL) | VAF 10/59 reads (17%) | called by mutect2, pindel
- SLC28A3 | c.910_912del p.Y304del | In Frame Del (DEL) | VAF 27/99 reads (27%) | called by pindel, varscan2
- SLTM | c.708del p.E237Kfs*27 | Frame Shift Del (DEL) | VAF 23/102 reads (23%) | called by mutect2, pindel, varscan2
- SUPT20HL1 | c.763G>T p.D255Y | Missense Mutation (SNP) | VAF 84/155 reads (54%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TMEM71 | c.397del p.S133Vfs*16 (on ENST00000523829 / NM_001382398.1; = p.S114Vfs*16 on NM_144649.3) | Frame Shift Del (DEL) | VAF 15/73 reads (21%) | called by mutect2, pindel, varscan2
- WDR11 | c.98del p.G33Vfs*2 | Frame Shift Del (DEL) | VAF 18/74 reads (24%) | called by mutect2, pindel, varscan2
- ZC3H10 | c.831_839del p.N277_A279del | In Frame Del (DEL) | VAF 11/52 reads (21%) | called by mutect2, pindel, varscan2
- ZNF26 | c.355del p.T119Pfs*17 | Frame Shift Del (DEL) | VAF 19/111 reads (17%) | called by mutect2, pindel, varscan2
- C14orf28 | c.243T>G p.S81= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as COSV100290072; called by muse, mutect2, varscan2
- DUSP16 | c.960T>C p.N320= | Silent (SNP) | VAF 34/106 reads (32%) | catalogued as rs1216413320, COSV99962972; called by muse, mutect2, varscan2
- EIF5 | c.603T>C p.D201= | Silent (SNP) | VAF 33/71 reads (46%) | catalogued as COSV99384679; called by muse, mutect2, varscan2
- GABRA3 | c.1005G>A p.A335= | Silent (SNP) | VAF 32/47 reads (68%) | catalogued as rs1298599586, COSV64802343; called by muse, mutect2, varscan2
- ITGB4 | c.2628G>A p.G876= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV99563512; called by muse, mutect2, varscan2
- KCNJ9 | c.258C>T p.R86= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as COSV63632641; called by muse, mutect2, varscan2
- MIB2 | c.195T>C p.A65= | Silent (SNP) | VAF 71/245 reads (29%) | catalogued as COSV100598746; called by muse, mutect2, varscan2
- MMP12 | c.147A>T p.P49= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as COSV100404836; called by muse, mutect2, varscan2
- MYCBPAP | c.1158G>A p.L386= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV100087792; called by muse, mutect2, varscan2
- OR4C11 | c.780G>A p.P260= | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as rs747998101, COSV56352745; called by muse, mutect2, varscan2
- PRPF19 | c.267C>T p.S89= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV57129073; called by muse, mutect2, varscan2
- PVR | c.1221T>A p.S407= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as COSV99495680; called by muse, mutect2
- RASGRF1 | c.438G>A p.L146= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV101369524; called by muse, mutect2, varscan2
- RETNLB | c.252G>A p.S84= | Silent (SNP) | VAF 86/323 reads (27%) | catalogued as rs780521444, COSV55466271; called by muse, mutect2, varscan2
- SERPINI2 | c.993G>T p.V331= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV99247629; called by muse, mutect2, varscan2
- SIRPB2 | c.387G>A p.R129= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as COSV100708407; called by muse, mutect2, varscan2
- SLC36A3 | c.1113G>A p.L371= | Silent (SNP) | VAF 34/170 reads (20%) | catalogued as rs776053455, COSV100077401; called by muse, mutect2, varscan2
- SYF2 | c.267G>A p.A89= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs755566111, COSV52574937; called by muse, mutect2, varscan2
- TOX2 | c.261G>A p.P87= (on ENST00000358131 / NM_001098798.2; = p.P36= on NM_032883.3) | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs988257733, COSV57887031; called by muse, mutect2, varscan2
- WAPL | c.2275C>T p.L759= | Silent (SNP) | VAF 35/115 reads (30%) | catalogued as COSV99556319; called by muse, mutect2, varscan2
- ZZEF1 | c.2793G>A p.A931= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs756310588, COSV101067577, COSV67560479; called by muse, mutect2, varscan2
- OBSCN | c.5138-1623C>T | Intron (SNP) | VAF 34/90 reads (38%) | catalogued as COSV99474116; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-18427C>T | Intron (SNP) | VAF 20/111 reads (18%) | catalogued as rs1356509251, COSV101043098; called by muse, mutect2, varscan2
